Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040039-09A.2 (aliquot TARGET-15-SJMPAL040039-09A.2-01D) from TARGET case TARGET-15-SJMPAL040039, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,089 days).
Specimen TARGET-15-SJMPAL040039-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6561aaab-e4fd-40e5-bf4e-628733ced728.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040039-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040039-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78b59bf6-dc37-4fbe-b00a-ae45046a7a88

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, In Frame Ins 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTTNBP2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753298694, COSV50483273; called by muse, mutect2, varscan2
- BIRC6 | c.4946C>A p.A1649E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.031); called by muse, mutect2
- CEP295 | c.5224C>A p.Q1742K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- DDX3X | c.1486G>A p.A496T (on ENST00000399959; = p.A497T on NM_001356.5) | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DYSF | c.4781A>G p.D1594G | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FBXW7 | c.1895_1896insGACTCC p.F632delinsLTP (on ENST00000281708 / NM_001349798.2; = p.F552delinsLTP on NM_018315.5) | In Frame Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel*
- GPA33 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- HSF5 | c.1590G>T p.L530F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.726); called by muse, mutect2
- HTT | c.1273+2C>A p.X425_splice | Splice Site (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- IGHV4-59 | c.347_349dup | In Frame Ins (INS) | VAF 21/30 reads (70%) | called by pindel, varscan2*
- NCAN | c.3880C>A p.H1294N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- NUTM2D | c.1824C>A p.D608E | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2
- NUTM2E | c.2040C>A p.D680E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); called by mutect2, varscan2
- POTED | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3703C>A p.H1235N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- CDCA3 | c.411A>G p.P137= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- DSE | c.1575G>A p.V525= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1489150219; called by muse, mutect2, varscan2
- DTNBP1 | c.255G>A p.A85= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs200096549, COSV100161193, COSV59039930; called by muse, mutect2, varscan2
- FAM171A2 | c.873C>T p.A291= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1261375329; called by muse, mutect2, varscan2
- STXBP3 | c.558C>A p.A186= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- GRM6 | c.1500+10C>A | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- XRCC4 | c.894-42302G>A | Intron (SNP) | VAF 29/49 reads (59%) | catalogued as rs768121949; called by muse, mutect2, varscan2
